TCGA case TCGA-XF-A9SX — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a648d9bf-cf37-41fc-9515-e8f5ac85fcd4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 719 days (2.0 years).

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 63.9 years (23,349 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension: Focal; Extracapsular extension present: Yes; Lymph nodes positive: 6; Lymph nodes tested: 71; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 136 days; Days to treatment end: 348 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 136 days; Days to treatment end: 348 days; Treatment outcome: Progressive Disease; Drug category: Platinum.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 65.2 years (23,824 days); Days to diagnosis: 475 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 475 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 475 days (1.3 years).
- Days to follow up: 719 days (2.0 years); Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 155 cm; BMI: 23.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking quit year: 2006; Age at onset: 24.
- Occupation type: Finance Professionals.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Esophageal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-A9SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 770 mg.
  Slide TCGA-XF-A9SX-01A-02-TSB: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-A9SX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-A9SX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: Accountant; Occupation primary industry: Clerical/Office Work; Tobacco smoking history indicator: 4; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No.
- Metastatic site list: Metastasis site: Lymph node only.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 719 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 719 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 475 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-A9SX-01A-21D-A390-01): tumor purity 0.5, ploidy 1.98, whole-genome doublings 0.
